Somatic mutation profile of tumor specimen TCGA-OR-A5JG-01A (aliquot TCGA-OR-A5JG-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JG, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.3 years (22,390 days).
Specimen TCGA-OR-A5JG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7208ceda-683c-4d47-964e-3bccd8b8ed5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JG-10A (Blood Derived Normal), aliquot TCGA-OR-A5JG-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37253416-d547-45df-b644-c621086956a3

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 21, Silent 7, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 98/115 reads (85%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ABCC9 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.714); catalogued as rs1181687706; called by muse, mutect2, varscan2
- ADARB1 | c.2041G>A p.G681S (on ENST00000360697 / NM_001346687.2; = p.G641S on NM_001112.4) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs763929833; called by muse, mutect2, varscan2
- ATP13A2 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 158/174 reads (91%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs756039984; called by muse, mutect2, varscan2
- ATXN2L | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1269710768; called by muse, mutect2, varscan2
- GATA5 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782105775; called by muse, varscan2
- MDM2 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 166/340 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.306); catalogued as rs1205651053; called by muse, mutect2, varscan2
- MUC16 | c.30275A>G p.D10092G | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as rs1348636305; called by muse, mutect2, varscan2
- PPP6R1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs908437763; called by muse, mutect2, varscan2
- SLC4A11 | c.2151G>C p.W717C | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101195925; called by muse, mutect2, varscan2
- TEX13A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1569406113; called by muse, mutect2, varscan2
- ZFYVE16 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs141062809; called by muse, mutect2, varscan2
- ATAD5 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- BCL3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GRIN2B | c.3041A>T p.Q1014L | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MAMLD1 | c.2304G>C p.R768S | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PATZ1 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDH7 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); called by muse, mutect2
- PHF14 | c.2719A>G p.K907E | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RELN | c.6572C>G p.S2191C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC44A1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SOCS5 | c.1434G>C p.R478S | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SREBF2 | c.1214del p.K405Rfs*5 | Frame Shift Del (DEL) | VAF 60/88 reads (68%) | called by mutect2, pindel, varscan2
- CHD7 | c.6753G>A p.S2251= | Silent (SNP) | VAF 133/160 reads (83%) | catalogued as rs755202253; called by muse, mutect2, varscan2
- MEFV | c.849G>A p.P283= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV54818767, COSV54820801; called by muse, mutect2, varscan2
- MTTP | c.729A>G p.L243= | Silent (SNP) | VAF 88/111 reads (79%) | called by muse, mutect2, varscan2
- MX2 | c.300C>T p.C100= | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- TAS2R41 | c.402G>T p.L134= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV101281471; called by muse, mutect2, varscan2
- ZNF134 | c.825A>G p.L275= | Silent (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
- ZNF229 | c.498C>T p.I166= | Silent (SNP) | VAF 102/188 reads (54%) | catalogued as rs185368876; called by muse, mutect2
